Somatic mutation profile of tumor specimen TCGA-64-1677-01A (aliquot TCGA-64-1677-01A-01W-0928-08) from TCGA case TCGA-64-1677, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 78.0 years (28,482 days).
Specimen TCGA-64-1677-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84974264-b654-4f88-bdd4-0ee18f90d7d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-64-1677-10A (Blood Derived Normal), aliquot TCGA-64-1677-10A-01W-0928-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0afe821-cb8e-487a-8fe5-92e7f9e3d137

The open-access MAF lists 222 somatic variants for this specimen: 162 protein-altering or splice-affecting, 55 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 144, Silent 55, Nonsense Mutation 7, Frame Shift Del 5, Splice Site 4, RNA 2, In Frame Del 1, 3'UTR 1, Nonstop Mutation 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 29/56 reads (52%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 40/234 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730882000, COSV52661847, COSV52680639, COSV52688008, COSV52782769; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB10 | c.766C>G p.L256V | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.291); catalogued as COSV60619322; called by muse, mutect2, varscan2
- ADAMTS20 | c.88C>A p.Q30K | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as COSV67125582; called by muse, mutect2, varscan2
- ADGRL3 | c.2578A>C p.N860H (on ENST00000506720 / NM_001322402.2; = p.N792H on NM_015236.6) | Missense Mutation (SNP) | VAF 34/377 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV72229077; called by muse, mutect2
- ADGRL4 | c.251G>A p.C84Y | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66058631, COSV66065099; called by muse, mutect2, varscan2
- ADGRV1 | c.3218C>G p.S1073C | Missense Mutation (SNP) | VAF 43/334 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67977349, COSV67996581; called by muse, mutect2, varscan2
- ANKLE2 | c.1379A>G p.K460R | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV61707586; called by muse, mutect2, varscan2
- ANOS1 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99390691; called by muse, mutect2, varscan2
- ARCN1 | c.1265T>C p.I422T | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as rs1565366603, COSV50614356; called by muse, mutect2, varscan2
- AREL1 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 35/647 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as COSV62665254; called by muse, mutect2
- ARHGEF15 | c.1520A>T p.Y507F | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV62724182; called by muse, mutect2, varscan2
- ATR | c.7735G>A p.E2579K | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.305); catalogued as COSV63383268; called by muse, mutect2, varscan2
- ATXN2 | c.3696C>A p.H1232Q (on ENST00000550104; = p.H1072Q on NM_002973.4) | Missense Mutation (SNP) | VAF 101/487 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0.158); catalogued as COSV57980864; called by muse, mutect2, varscan2
- BRINP3 | c.725-2A>T p.X242_splice | Splice Site (SNP) | VAF 16/81 reads (20%) | catalogued as COSV66511371; called by muse, mutect2, varscan2
- BRIP1 | c.3526A>C p.I1176L | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV51993239; called by muse, mutect2, varscan2
- C1QB | c.88A>C p.T30P | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV59244901; called by muse, mutect2, varscan2
- C8orf33 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1296789232, COSV58895241; called by muse, mutect2
- CCDC150 | c.777G>C p.Q259H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV55870957; called by muse, varscan2
- CCHCR1 | c.2113C>T p.L705F | Missense Mutation (SNP) | VAF 142/518 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV52534924; called by muse, mutect2, varscan2
- CDH20 | c.1555G>T p.D519Y | Missense Mutation (SNP) | VAF 42/278 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53003710; called by muse, mutect2, varscan2
- CDKL5 | c.592G>T p.G198C | Missense Mutation (SNP) | VAF 120/825 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66110032; called by muse, mutect2, varscan2
- CENPI | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV54500228; called by muse, mutect2, varscan2
- CORO1C | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1292307168, COSV54593770; called by muse, mutect2, varscan2
- CPS1 | c.3484C>T p.H1162Y | Missense Mutation (SNP) | VAF 96/336 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as CD110271, COSV51800577; called by muse, mutect2, varscan2
- CSGALNACT1 | c.43G>T p.V15L | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV59973115; called by muse, mutect2, varscan2
- CSPG5 | c.1432A>G p.T478A | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1487548767, COSV53129713; called by muse, mutect2, varscan2
- CTR9 | c.3313G>A p.E1105K | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV63727632; called by muse, mutect2, varscan2
- CUL4A | c.439-1G>C p.X147_splice (on ENST00000375440 / NM_001008895.4; = p.X47_splice on NM_003589.3) | Splice Site (SNP) | VAF 14/110 reads (13%) | catalogued as COSV100417136; called by muse, mutect2, varscan2
- CYP4B1 | c.491T>C p.M164T | Missense Mutation (SNP) | VAF 67/402 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754558644, COSV54720889; called by muse, mutect2, varscan2
- DACH2 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV64160578; called by muse, mutect2
- DCDC1 | c.4014G>T p.L1338F (on ENST00000597505 / NM_001367979.1; = p.L445F on NM_020869.3) | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs372263819; called by muse, mutect2, varscan2
- DMXL2 | c.3074G>A p.R1025H | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs138911498, COSV51840091; called by muse, mutect2, varscan2
- DNAH7 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 90/375 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1025250057, COSV56749839; called by muse, mutect2
- DRC1 | c.2078A>T p.Q693L | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV55494685; called by muse, mutect2, varscan2
- DSCAM | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as COSV68624580; called by muse, mutect2, varscan2
- DYSF | c.4238G>T p.R1413L | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50266134, COSV99243761; called by muse, varscan2
- EMILIN3 | c.2162G>A p.R721K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV60034905; called by muse, mutect2, varscan2
- EML2 | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55597209; called by muse, mutect2, varscan2
- ERLIN2 | c.433G>C p.D145H | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52419031; called by muse, mutect2, varscan2
- ESRRG | c.550C>A p.R184S | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV63148206, COSV63150211; called by muse, mutect2, varscan2
- FAM91A1 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV58235410; called by muse, mutect2
- FCRL3 | c.1358C>A p.A453E | Missense Mutation (SNP) | VAF 63/854 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63838990; called by muse, mutect2
- FLG2 | c.7136C>G p.S2379* | Nonsense Mutation (SNP) | VAF 50/349 reads (14%) | catalogued as COSV66166278; called by muse, mutect2, varscan2
- FSCN3 | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV50000004; called by muse, mutect2, varscan2
- FUT8 | c.1447C>T p.H483Y (on ENST00000360689 / NM_001371534.1; = p.H320Y on NM_004480.4) | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.248); catalogued as COSV61279021; called by muse, mutect2, varscan2
- GABRA2 | c.389A>C p.N130T | Missense Mutation (SNP) | VAF 40/315 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62911311; called by muse, mutect2, varscan2
- GHSR | c.445C>A p.L149I | Missense Mutation (SNP) | VAF 95/209 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV99576831; called by muse, mutect2, varscan2
- GLCE | c.276T>A p.N92K | Missense Mutation (SNP) | VAF 86/559 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV55944095; called by muse, mutect2, varscan2
- GPR148 | c.255C>A p.H85Q | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.405); catalogued as COSV59307438; called by muse, mutect2
- GPR85 | c.522C>A p.F174L | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as COSV51782492, COSV51783766; called by muse, mutect2
- GRIK3 | c.394C>A p.H132N | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.208); catalogued as COSV66134854; called by muse, mutect2, varscan2
- HEATR1 | c.1409G>T p.G470V | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.73); catalogued as COSV63979651; called by muse, mutect2, varscan2
- HIBADH | c.1010G>T p.*337Lext*29 | Nonstop Mutation (SNP) | VAF 23/84 reads (27%) | catalogued as COSV55311239; called by muse, mutect2, varscan2
- HIPK4 | c.1503C>A p.F501L | Missense Mutation (SNP) | VAF 29/282 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as COSV99396516; called by muse, mutect2, varscan2
- HSPA2 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99904813; called by muse, mutect2, varscan2
- IGHG4 | c.748A>G p.K250E | Missense Mutation (SNP) | VAF 64/892 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.254); catalogued as rs587751741; called by muse, mutect2
- IGSF10 | c.3032G>T p.G1011V | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56781094; called by muse, mutect2, varscan2
- IL1RAPL1 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0.068); catalogued as COSV56233799, COSV56250724; called by muse, mutect2, varscan2
- IL6R | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.091); catalogued as COSV59815107; called by muse, mutect2, varscan2
- INTS12 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV60861383; called by muse, mutect2
- IQCC | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.381); catalogued as COSV52207202, COSV52208749; called by muse, mutect2, varscan2
- IZUMO1R | c.580C>T p.R194W (on ENST00000440961; = p.R201W on NM_001199206.3) | Missense Mutation (SNP) | VAF 90/939 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs373625955; called by muse, mutect2
- KCNB2 | c.1949del p.P650Rfs*3 | Frame Shift Del (DEL) | VAF 21/105 reads (20%) | catalogued as COSV101578823; called by mutect2, pindel, varscan2
- KCNC2 | c.1648C>A p.P550T | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.024); catalogued as COSV54361311; called by muse, mutect2, varscan2
- KDM5C | c.898C>G p.H300D | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV64762385; called by muse, mutect2, varscan2
- KIAA1549L | c.1250C>G p.S417C (on ENST00000321505; = p.S714C on NM_012194.3) | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV55768959, COSV99682949; called by muse, mutect2, varscan2
- KIF27 | c.2178G>C p.M726I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52824738; called by muse, mutect2, varscan2
- KLHL3 | c.26G>C p.S9T | Missense Mutation (SNP) | VAF 145/633 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.03); catalogued as COSV59050443; called by muse, mutect2, varscan2
- KLRC1 | c.653C>G p.S218* | Nonsense Mutation (SNP) | VAF 78/377 reads (21%) | catalogued as COSV61724717; called by muse, mutect2, varscan2
- KMT2C | c.3537G>C p.L1179F | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV51274446; called by muse, mutect2
- KRT38 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 18/115 reads (16%) | catalogued as COSV99878146; called by muse, mutect2, varscan2
- KRT38 | c.684G>C p.Q228H | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99878148; called by mutect2, varscan2
- KRTAP1-3 | c.26G>C p.C9S | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV60335470; called by muse, varscan2
- LIN52 | c.10C>G p.P4A | Missense Mutation (SNP) | VAF 33/328 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.098); catalogued as rs921990374, COSV63245664; called by muse, mutect2, varscan2
- LRP1B | c.7258T>C p.W2420R | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67181912; called by muse, mutect2, varscan2
- LRRN3 | c.1738C>T p.L580F | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV57817261, COSV57825052; called by muse, mutect2
- MAEA | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.191); catalogued as COSV53261045; called by muse, mutect2, varscan2
- MAGEC1 | c.2425C>G p.P809A | Missense Mutation (SNP) | VAF 110/412 reads (27%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.092); catalogued as COSV53567235; called by muse, mutect2, varscan2
- MAP4K5 | c.606G>T p.W202C | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50152422; called by muse, mutect2, varscan2
- MAP7D2 | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 35/328 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.839); catalogued as COSV65525357; called by muse, mutect2, varscan2
- MAPKBP1 | c.1539G>C p.E513D (on ENST00000456763 / NM_001128608.2; = p.E507D on NM_014994.3) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52957487; called by mutect2, varscan2
- MED1 | c.3671C>T p.P1224L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs761559810, COSV56122039; called by muse, mutect2, varscan2
- MGAT4C | c.1202G>C p.R401P | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV59829278; called by muse, mutect2, varscan2
- MMP14 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.034); catalogued as COSV61287270; called by muse, mutect2, varscan2
- MMS19 | c.323C>G p.S108C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.619); catalogued as COSV59133472; called by muse, mutect2, varscan2
- MOCS3 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.164); catalogued as COSV54865466; called by muse, mutect2, varscan2
- MTREX | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV57923699; called by muse, mutect2, varscan2
- MTSS1 | c.618+2T>C p.X206_splice | Splice Site (SNP) | VAF 59/280 reads (21%) | catalogued as COSV61494399; called by muse, mutect2, varscan2
- MYH13 | c.5029A>G p.I1677V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV52819848; called by muse, mutect2, varscan2
- NAV3 | c.2555G>T p.S852I | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV57058801; called by muse, mutect2, varscan2
- NFIA | c.747G>C p.L249F | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV64533265; called by muse, mutect2
- NLRP2 | c.82T>A p.Y28N | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV54751843; called by muse, mutect2
- NLRP8 | c.1639G>C p.G547R | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV52582719, COSV52587771; called by muse, mutect2, varscan2
- NRAP | c.4156C>G p.H1386D (on ENST00000359988 / NM_001322945.2; = p.H1351D on NM_006175.4) | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100748297, COSV63488177; called by muse, mutect2
- NTNG2 | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as rs772689013, COSV100647373; called by mutect2, varscan2
- NUP153 | c.2568C>G p.D856E | Missense Mutation (SNP) | VAF 72/827 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV50446013; called by muse, mutect2
- ONECUT2 | c.1332C>G p.I444M | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101525699, COSV72153286; called by muse, mutect2, varscan2
- OPHN1 | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.541); catalogued as COSV62779818, COSV62780403; called by muse, mutect2, varscan2
- OR2M4 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 95/388 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.674); catalogued as COSV60707065; called by muse, mutect2, varscan2
- OR51A2 | c.239T>A p.L80Q | Missense Mutation (SNP) | VAF 121/296 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100985029; called by muse, mutect2, varscan2
- OR5D18 | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 72/895 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV61735997; called by muse, mutect2
- OVCH2 | c.976C>A p.H326N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV71952620; called by muse, mutect2, varscan2
- P2RY4 | c.946C>G p.Q316E | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as COSV100997000; called by muse, mutect2, varscan2
- PCDHA10 | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 7/90 reads (8%) | catalogued as COSV56474485; called by muse, mutect2
- PCDHGA11 | c.557G>A p.R186K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1293113918, COSV53891955, COSV54048929; called by muse, mutect2, varscan2
- PCK1 | c.845C>A p.A282D | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60125892; called by muse, mutect2, varscan2
- PCLO | c.3401C>T p.A1134V | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs751754924, COSV100428273, COSV61612573; called by muse, mutect2, varscan2
- PCM1 | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV61514316; called by muse, mutect2, varscan2
- PEG3 | c.2663A>T p.N888I | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV55623230; called by muse, mutect2, varscan2
- PNCK | c.514G>A p.A172T (on ENST00000340888 / NM_001366975.1; = p.A255T on NM_001039582.3) | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs782561753, COSV61742363; called by muse, mutect2, varscan2
- POC5 | c.1151A>C p.K384T (on ENST00000428202 / NM_001099271.2; = p.K359T on NM_152408.2) | Missense Mutation (SNP) | VAF 21/290 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); catalogued as COSV100994316; called by muse, mutect2
- POLE | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs747005851, COSV57673117; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLK | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54031258; called by muse, mutect2
- POLR1F | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV55997646; called by muse, mutect2
- POLR1F | c.461C>G p.S154C | Missense Mutation (SNP) | VAF 45/326 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55997656; called by muse, mutect2, varscan2
- POLR3B | c.2870G>T p.R957I | Missense Mutation (SNP) | VAF 56/369 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV57275473; called by muse, mutect2, varscan2
- PPP2R5E | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV61740175, COSV61740781; called by muse, mutect2, varscan2
- PRR19 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs201517615, COSV100003731; called by muse, mutect2, varscan2
- PWWP3B | c.736G>C p.D246H | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.935); catalogued as COSV100531090; called by muse, mutect2
- RAB3IL1 | c.375G>T p.M125I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57116693; called by muse, varscan2
- RAG1 | c.2027G>C p.S676T | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as COSV55023758; called by muse, mutect2, varscan2
- RHEX | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV100520055, COSV58979987; called by muse, mutect2, varscan2
- RIMS2 | c.1668C>A p.S556R (on ENST00000666250 / NM_001348490.2; = p.S364R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/384 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.927); catalogued as COSV51649452; called by muse, mutect2, varscan2
- RIPPLY1 | c.238G>C p.G80R | Missense Mutation (SNP) | VAF 48/701 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.431); catalogued as COSV99343613; called by muse, mutect2
- RNF20 | c.2642G>C p.R881P | Missense Mutation (SNP) | VAF 145/516 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66660169; called by muse, mutect2, varscan2
- RPL19 | c.235G>T p.G79C | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56634692; called by muse, mutect2, varscan2
- RXFP2 | c.572A>G p.Y191C | Missense Mutation (SNP) | VAF 54/349 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53632627; called by muse, mutect2, varscan2
- SCAMP3 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 26/170 reads (15%) | catalogued as COSV56943505; called by muse, mutect2, varscan2
- SIGLEC9 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 32/164 reads (20%) | catalogued as COSV51582327; called by muse, mutect2, varscan2
- SLC17A6 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV54133138; called by muse, mutect2, varscan2
- SLC35A5 | c.601A>G p.R201G | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV53725948; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2146G>T p.D716Y (on ENST00000540229 / NM_001371097.1; = p.D655Y on NM_001009562.4) | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV67439734, COSV67445996; called by muse, mutect2, varscan2
- SLITRK2 | c.1766T>A p.V589D | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.058); catalogued as COSV59422581; called by muse, mutect2, varscan2
- SPATA5 | c.1795C>G p.L599V | Missense Mutation (SNP) | VAF 107/410 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as COSV56771033; called by muse, mutect2, varscan2
- SPTBN2 | c.2345C>T p.T782M | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755618733, COSV59445812; called by muse, mutect2, varscan2
- STK25 | c.743A>T p.E248V | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV50868821; called by muse, mutect2
- SUOX | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as rs201490900, COSV56266523; called by muse, mutect2, varscan2
- SYNE1 | c.10357G>T p.G3453W (on ENST00000367255 / NM_182961.4; = p.G3460W on NM_033071.3) | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs139823841, COSV54895243; called by muse, mutect2, varscan2
- TBR1 | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV67417086; called by muse, mutect2
- TCEANC | c.40A>G p.I14V (on ENST00000380600 / NM_001297563.2; = p.I44V on NM_152634.4) | Missense Mutation (SNP) | VAF 38/343 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as COSV100124629; called by muse, mutect2, varscan2
- TCF7 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs972016552, COSV100389853; called by muse, mutect2, varscan2
- TCHH | c.1745A>T p.E582V | Missense Mutation (SNP) | VAF 8/74 reads (11%) | PolyPhen possibly damaging (0.763); catalogued as COSV64272314; called by mutect2, varscan2
- TCP1 | c.422A>G p.D141G | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.178); catalogued as rs754010854, COSV58457216; called by muse, mutect2, varscan2
- TRERF1 | c.2546T>G p.L849W | Missense Mutation (SNP) | VAF 24/313 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61666424; called by muse, mutect2
- TRMT5 | c.449C>G p.S150C | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); catalogued as COSV99712018; called by muse, mutect2, varscan2
- TRPA1 | c.1403A>T p.D468V | Missense Mutation (SNP) | VAF 68/324 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as rs767840901, COSV51554836, COSV51566849; called by muse, mutect2, varscan2
- TSHZ3 | c.3211C>A p.H1071N | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53663099, COSV99552192; called by muse, mutect2, varscan2
- UGT3A2 | c.1238A>G p.K413R | Missense Mutation (SNP) | VAF 109/711 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.186); catalogued as COSV56928002; called by muse, mutect2, varscan2
- ZBED9 | c.1729G>A p.D577N | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); catalogued as COSV71729127, COSV71729527; called by muse, mutect2
- ZFHX4 | c.2678C>G p.S893* | Nonsense Mutation (SNP) | VAF 9/118 reads (8%) | catalogued as COSV50478715; called by muse, mutect2
- ZNF112 | c.2551C>T p.H851Y (on ENST00000337401 / NM_001083335.2; = p.H845Y on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/490 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100495615; called by muse, mutect2, varscan2
- ZNF225 | c.110T>A p.M37K | Missense Mutation (SNP) | VAF 214/1422 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53470741; called by muse, mutect2, varscan2
- ZNF503 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as COSV65307156; called by muse, mutect2
- ZNF568 | c.1409G>C p.G470A | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV61740278, COSV61741306; called by muse, mutect2, varscan2
- ZNF571 | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 72/382 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as rs775259902, COSV100143655, COSV60734345; called by muse, mutect2, varscan2
- GDF2 | c.737del p.P246Qfs*27 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- POGZ | c.3221_3229del p.R1074_M1076del | In Frame Del (DEL) | VAF 22/268 reads (8%) | called by mutect2, pindel
- SLCO1C1 | c.989del p.G330Efs*6 | Frame Shift Del (DEL) | VAF 27/80 reads (34%) | called by mutect2, pindel, varscan2
- STXBP4 | c.1305+3_1305+6del p.X435_splice | Splice Site (DEL) | VAF 12/57 reads (21%) | called by mutect2, pindel, varscan2
- TEX35 | c.434del p.G145Efs*45 | Frame Shift Del (DEL) | VAF 38/344 reads (11%) | called by mutect2, pindel, varscan2
- TP53 | c.142_151del p.D48Nfs*72 | Frame Shift Del (DEL) | VAF 177/1433 reads (12%) | called by mutect2, pindel, varscan2
- AASDHPPT | c.93C>G p.A31= | Silent (SNP) | VAF 19/133 reads (14%) | catalogued as COSV53788153, COSV53788560; called by muse, mutect2, varscan2
- ABCC1 | c.3936C>T p.H1312= | Silent (SNP) | VAF 30/264 reads (11%) | catalogued as rs369198761; called by muse, mutect2, varscan2
- AHNAK2 | c.2461C>T p.L821= | Silent (SNP) | VAF 32/192 reads (17%) | catalogued as rs753675332, COSV60906374; called by muse, mutect2, varscan2
- AKAP5 | c.600C>T p.S200= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV57742012; called by muse, mutect2, varscan2
- ALK | c.1998C>A p.P666= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV101200768, COSV66555521, COSV66572515; called by muse, mutect2, varscan2
- ALPK2 | c.2619G>T p.V873= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV100864255; called by muse, mutect2
- C1orf74 | c.156A>T p.P52= | Silent (SNP) | VAF 29/258 reads (11%) | catalogued as COSV50550384; called by muse, mutect2, varscan2
- CAPN3 | c.483G>A p.G161= | Silent (SNP) | VAF 45/230 reads (20%) | catalogued as CD062125, COSV58818832; called by muse, mutect2, varscan2
- CCDC170 | c.255G>A p.E85= | Silent (SNP) | VAF 24/232 reads (10%) | catalogued as COSV53336206; called by muse, mutect2, varscan2
- CDH12 | c.2238C>T p.S746= | Silent (SNP) | VAF 52/243 reads (21%) | catalogued as rs766384231, COSV66385669; called by muse, mutect2, varscan2
- CHRNB3 | c.27C>A p.L9= | Silent (SNP) | VAF 26/249 reads (10%) | catalogued as COSV51492872; called by muse, mutect2
- CIDEA | c.447C>A p.A149= | Silent (SNP) | VAF 41/232 reads (18%) | catalogued as COSV57597045; called by muse, mutect2, varscan2
- CUL4A | c.1206C>T p.P402= (on ENST00000375440 / NM_001008895.4; = p.P302= on NM_003589.3) | Silent (SNP) | VAF 20/255 reads (8%) | called by muse, mutect2
- DCST2 | c.1311G>A p.R437= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as COSV55049880; called by muse, mutect2
- DSG1 | c.2259T>A p.P753= | Silent (SNP) | VAF 68/368 reads (18%) | catalogued as COSV57132906; called by muse, varscan2
- DUSP29 | c.150C>G p.P50= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV58299888; called by muse, mutect2
- ENO1 | c.72C>G p.L24= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as COSV52302536; called by muse, mutect2, varscan2
- FAM83B | c.2484T>C p.P828= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV60918807; called by muse, mutect2, varscan2
- GRIK1 | c.2028A>T p.V676= | Silent (SNP) | VAF 18/166 reads (11%) | catalogued as COSV58709346; called by muse, mutect2, varscan2
- H2AC1 | c.261G>A p.A87= | Silent (SNP) | VAF 42/262 reads (16%) | catalogued as rs1393154649, COSV51236665; called by muse, mutect2, varscan2
- HGSNAT | c.555C>G p.L185= | Silent (SNP) | VAF 36/116 reads (31%) | catalogued as COSV65531846; called by muse, mutect2, varscan2
- IFIT1B | c.1326C>T p.L442= | Silent (SNP) | VAF 123/624 reads (20%) | catalogued as COSV65663227; called by muse, mutect2, varscan2
- IL21R | c.807C>A p.A269= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs746467550, COSV61968088; called by muse, mutect2, varscan2
- IMMP1L | c.207G>T p.V69= | Silent (SNP) | VAF 26/131 reads (20%) | catalogued as COSV53442409; called by muse, mutect2, varscan2
- KLHL38 | c.15A>G p.S5= | Silent (SNP) | VAF 51/305 reads (17%) | catalogued as COSV58085805; called by muse, mutect2, varscan2
- KNL1 | c.231G>C p.V77= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV61150520; called by muse, mutect2, varscan2
- LCN12 | c.177G>A p.A59= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs760748731, COSV65421514, COSV65422324; called by muse, mutect2, varscan2
- LRFN5 | c.1584C>G p.T528= | Silent (SNP) | VAF 76/701 reads (11%) | catalogued as COSV53241123; called by muse, varscan2
- LRRTM4 | c.1518C>T p.C506= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs1384875684, COSV69138768; called by muse, mutect2, varscan2
- MYH1 | c.2076T>A p.L692= | Silent (SNP) | VAF 20/172 reads (12%) | catalogued as COSV56842981; called by muse, mutect2, varscan2
- NTNG2 | c.390C>A p.T130= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100647369; called by mutect2, varscan2
- OR51A2 | c.240G>T p.L80= | Silent (SNP) | VAF 125/294 reads (43%) | catalogued as COSV100985028; called by muse, mutect2, varscan2
- P2RX6 | c.579C>A p.A193= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV60382210; called by muse, mutect2, varscan2
- PARN | c.1467G>A p.E489= | Silent (SNP) | VAF 104/640 reads (16%) | catalogued as rs771877532, COSV58363391; called by muse, mutect2, varscan2
- PCDHB3 | c.1596C>T p.G532= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs782150356, COSV50563873; called by muse, mutect2, varscan2
- PDE11A | c.1266C>T p.R422= | Silent (SNP) | VAF 26/292 reads (9%) | catalogued as COSV53684738; called by muse, mutect2
- PHB2 | c.484C>T p.L162= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV54640764; called by muse, mutect2, varscan2
- PHF20L1 | c.1962G>A p.L654= | Silent (SNP) | VAF 29/251 reads (12%) | catalogued as COSV55188074, COSV55199825; called by muse, mutect2, varscan2
- PLEC | c.10182C>T p.I3394= (on ENST00000322810 / NM_201380.4; = p.I3284= on NM_000445.5) | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV59598828; called by muse, mutect2, varscan2
- PLPP4 | c.585C>T p.S195= | Silent (SNP) | VAF 30/352 reads (9%) | catalogued as COSV64826418; called by muse, mutect2
- PPIF | c.462C>T p.F154= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as COSV56550803; called by muse, mutect2
- PXN | c.1584C>T p.H528= (on ENST00000228307 / NM_001080855.3; = p.H494= on NM_002859.4) | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs548963687, COSV57216857; called by muse, mutect2, varscan2
- RAD51AP2 | c.624T>A p.I208= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as COSV67587210; called by muse, mutect2, varscan2
- RALGPS2 | c.33C>G p.V11= | Silent (SNP) | VAF 34/324 reads (10%) | catalogued as COSV61335105; called by muse, mutect2, varscan2
- RHOBTB3 | c.843C>T p.F281= | Silent (SNP) | VAF 43/198 reads (22%) | catalogued as COSV66101081; called by muse, varscan2
- SDK1 | c.3114C>A p.L1038= | Silent (SNP) | VAF 16/161 reads (10%) | catalogued as COSV67354581; called by muse, mutect2
- SHROOM4 | c.3198G>T p.A1066= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV56788091, COSV99173192; called by muse, mutect2
- SLC18A3 | c.573C>T p.F191= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV60319364; called by muse, mutect2, varscan2
- SMAD3 | c.717G>A p.E239= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as COSV100528872; called by muse, mutect2, varscan2
- ST8SIA1 | c.594C>T p.N198= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV53949899; called by muse, mutect2, varscan2
- TAF3 | c.1533G>A p.E511= | Silent (SNP) | VAF 25/269 reads (9%) | catalogued as rs759041540, COSV60202730; called by muse, mutect2, varscan2
- TCF19 | c.546C>A p.L182= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV52562787, COSV52563712; called by muse, mutect2
- XAB2 | c.222C>T p.Y74= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs781557480, COSV60696602; called by muse, mutect2, varscan2
- ZCCHC9 | c.774G>T p.P258= | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as rs768212184, COSV54175853, COSV99562618; called by muse, mutect2, varscan2
- ZNF425 | c.1362G>A p.R454= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV65200482; called by muse, mutect2, varscan2
- BTN2A3P | n.1065del | RNA (DEL) | VAF 72/391 reads (18%) | called by mutect2, pindel*, varscan2
- MIR516B2 | n.10G>A | RNA (SNP) | VAF 13/129 reads (10%) | catalogued as rs777947841; called by muse, mutect2
- NTRK3 | c.1586-40581G>C | Intron (SNP) | VAF 47/218 reads (22%) | catalogued as COSV100446255; called by muse, mutect2, varscan2
- RNU6-1178P | chr17:20895729 G>T | 5'Flank (SNP) | VAF 44/355 reads (12%) | catalogued as COSV60000185; called by muse, mutect2, varscan2
- TAF9 | c.*2C>G | 3'UTR (SNP) | VAF 63/365 reads (17%) | catalogued as COSV99472667; called by muse, mutect2, varscan2
